HCMI case HCM-WCMC-0945-C54 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a826f214-8322-443e-b8a9-8495c5d81b2f

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1957; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 65.0 years (23,744 days); AJCC staging edition: 8th; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G1; Prior malignancy: no; Prior treatment: No.
   Pathology details: Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 26 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Days to follow up: 215 days; Disease response: Stable Disease; Progression or recurrence: No.

Molecular and laboratory tests
- MLH1 (IHC): Negative.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PMS2 (IHC): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 93.1 kg; Height: 163.3 cm; BMI: 34.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-0945-C54-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-WCMC-0945-C54-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
  Slide HCM-WCMC-0945-C54-01A-01-S3-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample HCM-WCMC-0945-C54-11A: Sample type: Slides; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample HCM-WCMC-0945-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
